Somatic mutation profile of tumor specimen MP2PRT-PAPRNM-TMP1-A (aliquot MP2PRT-PAPRNM-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPRNM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (707 days).
Specimen MP2PRT-PAPRNM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41da3071-60aa-47f4-9066-89273bf56f06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPRNM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPRNM-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b93ba38-b792-48df-a3b1-201663a0a1d8

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 142/363 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs753353080, COSV60695108; called by muse, mutect2, varscan2
- FRY | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778573468, COSV100968683; called by muse, mutect2, varscan2
- MAN2A2 | c.2719G>A p.V907M | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1189854269; called by muse, mutect2
- TRIM29 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 54/718 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV100531812; called by muse, mutect2
- RP1 | c.4166A>G p.Y1389C | Missense Mutation (SNP) | VAF 105/159 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
